Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7QH, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7QH-01C (Primary Tumor).

[page 1 of 2]
MEDICAL RECORD

Surgical Pathology Report

Surgical Pathology Report

PATIENT:
ACCOUNT#:
DOB:
AGE:
ATTENDING:
REQUESTING:
CONTACT NO:
COPIES TO:

SEX: M

MRN:
RECEIVED DATE:
PROCEDURE DATE:
SIGN-OUT DATE:
LOCATION:
ROOM:

DIAGNOSIS:

ICD O-3
Carcinoma, renal cell chromophobe type 8317/3
Site: @ Kidney NOS C64.9 *9/24/13*

1. Kidney, right (specimens 1&2, excision): Renal cell carcinoma with chromophobe features, Fuhrman nuclear Grade II/IV.
2. Rib (biopsy): A piece of unremarkable rib, gross diagnosis only.

CLINICAL INFORMATION: HISTORY:

MAN WITH BHD

PROCEDURE: PREOP DX:#SOLID RENAL MASS POSTOP DX: SOLID RENAL MASS OPERATIVE FINDINGS:
3 CM SOLID MASS IN MID POLE OF RIGHT KIDNEY AND .5 CM MASS IN POSTERIOR ASPECT OF RIGHT KIDNEY

SPECIMENS SUBMITTED: 1) KIDNEY, RIGHT
2) KIDNEY, RIGHT
3) RIB

GROSS DESCRIPTION: Received are three (3) containers labeled with the patient's name and number.

1. "Solid" contains a single fragment of yellow-white soft tissue measuring 0.9 X 0.7 X 0.5 cm. The fragment of tissue has been previously incised and has a gold-mahogany cut surface. A portion is retained in and the remainder is submitted in cassettes labeled 1A and 1B.
2. "Solid #2" contains a single fragment of soft, red-tan-gold soft tissue measuring 4.2 X 3.5 X 2.5 cm. overall. The specimen represents a solitary mass measuring 2.8 X 3.5 X 2.5 cm. with attached fibroadipose tissue in grossly-appearing normal kidney. The specimen has been previously incised and reveals a red, friable cut surface with areas of gold-tan tissue. No discernable capsule is appreciated. Representative portions are retained in and representative portions are submitted in cassettes 2A-2F.

Patient Identification

[page 2 of 2]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

3. "Right rib" consists of a single fragment of tissue, consistent with rib with minimal soft tissue measuring 1.0 X 0.5 X 7.0 cm. The specimen is submitted for gross diagnosis only.

Printed

Criteria	lv 9/12/13	Yes	No

Patient Identification

Source: NCI Genomic Data Commons file 338174ef-4f5f-4e33-8360-2748656d86ad (TCGA-KM-A7QH.030DC904-C959-4D06-AE70-C99AFAAB31E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).